Somatic mutation profile of tumor specimen 0DVKG7 from CCDI case PBCMZJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Embryonal sarcoma; Tissue or organ of origin: Liver; Age at diagnosis: 12.4 years (4,534 days).
Specimen 0DVKG7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) af39f0a2-88d2-4a49-89e9-23b9d989c816.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVKG9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1d9d3ced-9e99-4f82-9435-361260c1f302

The open-access MAF lists 32 somatic variants for this specimen: 26 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 4, Frame Shift Del 2, Intron 1, In Frame Del 1, Nonsense Mutation 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR2 | c.755C>G p.S252W | Missense Mutation (SNP) | VAF 95/401 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs79184941, CM950458, CM970526, COSV60638319; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- C1orf109 | c.482C>T p.S161L | Missense Mutation (SNP) | VAF 73/550 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.013); catalogued as rs766285884, COSV63656831; called by muse, mutect2, varscan2
- CTNND2 | c.3415C>T p.Q1139* | Nonsense Mutation (SNP) | VAF 77/464 reads (17%) | catalogued as COSV100474843; called by muse, mutect2, varscan2
- KPNA1 | c.1298C>G p.T433R | Missense Mutation (SNP) | VAF 54/525 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); catalogued as COSV60270302; called by muse, mutect2, varscan2
- NRXN2 | c.3598G>A p.V1200M | Missense Mutation (SNP) | VAF 41/336 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs780057301; called by muse, mutect2, varscan2
- THSD7B | c.175G>A p.G59R | Missense Mutation (SNP) | VAF 143/703 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs775249555, COSV55674045, COSV55742842; called by muse, mutect2, varscan2
- USP35 | c.2462G>A p.R821H | Missense Mutation (SNP) | VAF 46/402 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs868630350, COSV60866399; called by muse, mutect2, varscan2
- ARID1A | c.5310_5326del p.P1771Rfs*7 | Frame Shift Del (DEL) | VAF 87/527 reads (17%) | called by mutect2, varscan2*
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 31/1084 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- CLGN | c.576T>G p.H192Q | Missense Mutation (SNP) | VAF 144/618 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, varscan2
- CNN3 | c.455T>G p.F152C | Missense Mutation (SNP) | VAF 92/728 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, varscan2
- DNAH7 | c.782T>C p.L261S | Missense Mutation (SNP) | VAF 32/674 reads (5%) | SIFT tolerated (0.76); PolyPhen benign (0.021); called by muse, mutect2
- DSC2 | c.407G>T p.R136I | Missense Mutation (SNP) | VAF 128/645 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EPHA5 | c.945C>A p.H315Q | Missense Mutation (SNP) | VAF 94/442 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM83H | c.62C>G p.P21R | Missense Mutation (SNP) | VAF 20/563 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); called by muse, mutect2
- FERD3L | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 34/279 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HS3ST3B1 | c.320G>C p.G107A | Missense Mutation (SNP) | VAF 91/396 reads (23%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- KCNIP2 | c.256G>T p.V86L (on ENST00000356640 / NM_173191.3; = p.V101L on NM_014591.5) | Missense Mutation (SNP) | VAF 50/291 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MPHOSPH9 | c.2652A>G p.I884M | Missense Mutation (SNP) | VAF 24/962 reads (2%) | SIFT tolerated (0.12); PolyPhen benign (0.06); called by muse, mutect2
- P3H3 | c.853+1G>T p.X285_splice | Splice Site (SNP) | VAF 44/292 reads (15%) | called by mutect2, varscan2
- PTER | c.726G>C p.L242F | Missense Mutation (SNP) | VAF 68/434 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.695); called by muse, mutect2
- RXRG | c.419_427del p.A140_C142del | In Frame Del (DEL) | VAF 104/608 reads (17%) | called by mutect2, varscan2
- TBX5 | c.882G>C p.E294D | Missense Mutation (SNP) | VAF 90/414 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.018); called by muse, varscan2
- TNFRSF6B | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 54/281 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TNXB | c.9286del p.E3096Sfs*2 (on ENST00000647633; = p.E2849Sfs*2 on NM_019105.8 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 122/318 reads (38%) | called by mutect2, varscan2
- VILL | c.1026G>C p.Q342H | Missense Mutation (SNP) | VAF 73/485 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- HLA-G | c.519G>A p.A173= | Silent (SNP) | VAF 62/298 reads (21%) | catalogued as COSV64406998; called by muse, mutect2, varscan2
- HYDIN | c.7581G>A p.E2527= | Silent (SNP) | VAF 37/378 reads (10%) | called by muse, varscan2
- LCLAT1 | c.510C>T p.F170= | Silent (SNP) | VAF 17/441 reads (4%) | called by muse, mutect2
- SEC31B | c.2760A>T p.P920= | Silent (SNP) | VAF 26/208 reads (13%) | called by muse, mutect2, varscan2
- CAPZB | c.4-29130G>C | Intron (SNP) | VAF 79/569 reads (14%) | called by muse, mutect2, varscan2
- FBLL1 | c.*17G>A | 3'UTR (SNP) | VAF 58/130 reads (45%) | catalogued as rs776500205; called by muse, mutect2, varscan2
